Somatic mutation profile of tumor specimen TCGA-3A-A9IV-01A (aliquot TCGA-3A-A9IV-01A-11D-A40W-08) from TCGA case TCGA-3A-A9IV, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 59.5 years (21,732 days).
Specimen TCGA-3A-A9IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 095ac9c2-7c7d-4554-a0c7-32b6a9a0ff45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IV-10A (Blood Derived Normal), aliquot TCGA-3A-A9IV-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbd94f2-8e66-4fe2-9e56-b369ad265891

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 5, RNA 2, In Frame Del 2, Splice Site 2, Splice Region 1, Frame Shift Del 1, 3'Flank 1, Intron 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.6697G>A p.V2233I (on ENST00000394518 / NM_007200.5; = p.V2237I on NM_006738.6) | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs376932632, COSV100773340; called by muse, mutect2, varscan2
- ATM | c.9089G>T p.G3030V | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876658529, COSV53736717, COSV53762839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB4 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 131/535 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100971405; called by muse, mutect2, varscan2
- CAB39L | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 250/661 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100759529; called by muse, mutect2
- CCDC130 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99237317; called by muse, mutect2, varscan2
- CCDC71L | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs779188005, COSV100273030; called by muse, varscan2
- CHD6 | c.6050G>A p.G2017E | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.033); catalogued as COSV100950758; called by muse, mutect2, varscan2
- CMYA5 | c.8465C>T p.S2822L | Missense Mutation (SNP) | VAF 164/249 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV71407642; called by muse, mutect2, varscan2
- CYP2C8 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs778008122, COSV100987901; called by muse, mutect2, varscan2
- DOCK2 | c.5111G>A p.R1704K | Missense Mutation (SNP) | VAF 181/301 reads (60%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.952); catalogued as COSV99911104; called by muse, mutect2, varscan2
- ERBIN | c.3086A>G p.N1029S | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV99396324; called by muse, mutect2, varscan2
- FOXG1 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 107/543 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.006); catalogued as COSV100486624; called by muse, mutect2, varscan2
- HMGCR | c.1971G>T p.M657I | Missense Mutation (SNP) | VAF 141/451 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99843121; called by muse, mutect2, varscan2
- HSPA1A | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 132/233 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as rs777027010, COSV100989361; called by muse, varscan2
- HTR3D | c.1306C>T p.L436F (on ENST00000382489 / NM_001163646.2; = p.L261F on NM_182537.3) | Missense Mutation (SNP) | VAF 359/428 reads (84%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs1374753560, COSV100487966; called by muse, mutect2, varscan2
- KCNA6 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 225/400 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV99768461; called by muse, mutect2, varscan2
- KCNA6 | c.763G>C p.G255R | Missense Mutation (SNP) | VAF 296/490 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV54975156, COSV99768463; called by muse, mutect2, varscan2
- KLF12 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 286/689 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs757861922, COSV100888433; called by muse, mutect2, varscan2
- KLRC4 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 128/489 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.425); catalogued as COSV100511270; called by muse, mutect2, varscan2
- MACF1 | c.7612G>A p.E2538K | Missense Mutation (SNP) | VAF 113/319 reads (35%) | catalogued as rs371939396; called by muse, mutect2, varscan2
- METTL4 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 96/494 reads (19%) | catalogued as rs761861713, COSV55249569, COSV99859518; called by muse, mutect2, varscan2
- MYO5A | c.3703C>T p.P1235S | Missense Mutation (SNP) | VAF 157/482 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100697460; called by muse, mutect2, varscan2
- NSUN5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 21/628 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99392288; called by muse, mutect2
- NTRK1 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693214; called by muse, mutect2, varscan2
- OTOP3 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 180/296 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172697; called by muse, mutect2, varscan2
- PCDHGB7 | c.2402_2404del p.K801del | In Frame Del (DEL) | VAF 149/289 reads (52%) | catalogued as rs749213635; called by pindel, varscan2
- RASA1 | c.2346T>C p.D782= | Splice Region (SNP) | VAF 230/395 reads (58%) | catalogued as COSV99169676; called by muse, mutect2, varscan2
- RILPL1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 84/967 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs754515711, COSV100525980; called by muse, mutect2
- RNF114 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 162/411 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as COSV54868737, COSV99724700; called by muse, mutect2, varscan2
- SIGLEC15 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 185/460 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV101248776; called by muse, mutect2, varscan2
- SMARCAL1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs753533155, COSV100619825; called by muse, mutect2, varscan2
- SPATA22 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 157/651 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV99279185; called by muse, mutect2, varscan2
- SRSF6 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs147863077; called by muse, mutect2, varscan2
- SYNE1 | c.1932+1G>A p.X644_splice (on ENST00000367255 / NM_182961.4; = p.X651_splice on NM_033071.3) | Splice Site (SNP) | VAF 233/275 reads (85%) | catalogued as COSV99557525; called by muse, mutect2, varscan2
- SYNE2 | c.8393C>T p.T2798I | Missense Mutation (SNP) | VAF 268/590 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1200723891, COSV100647129; called by muse, mutect2, varscan2
- TRIM47 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 224/373 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs371497987; called by muse, mutect2, varscan2
- ZNF714 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 95/672 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377697860; called by muse, mutect2, varscan2
- ZNF85 | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs746942638, COSV100059594; called by muse, mutect2
- ATRX | c.6700_6726del p.D2234_Q2242del | In Frame Del (DEL) | VAF 139/326 reads (43%) | called by pindel, varscan2
- KDM3B | c.3607_3608del p.S1203* | Frame Shift Del (DEL) | VAF 76/293 reads (26%) | called by mutect2, pindel, varscan2
- PIAS1 | c.466_469+1del p.X156_splice | Splice Site (DEL) | VAF 64/94 reads (68%) | called by mutect2, varscan2
- ACP7 | c.1242G>A p.S414= | Silent (SNP) | VAF 83/284 reads (29%) | catalogued as rs151134063; called by muse, mutect2, varscan2
- MOCS1 | c.1122G>A p.Q374= | Silent (SNP) | VAF 71/192 reads (37%) | catalogued as COSV99224978; called by muse, varscan2
- RRAD | c.726G>T p.A242= | Silent (SNP) | VAF 170/202 reads (84%) | catalogued as COSV100233743; called by muse, mutect2, varscan2
- THBS1 | c.1938C>T p.P646= | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as COSV52949924; called by muse, mutect2, varscan2
- ZNF28 | c.972G>A p.G324= | Silent (SNP) | VAF 168/543 reads (31%) | catalogued as rs1310013231, COSV100354354; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502139 del G | 5'Flank (DEL) | VAF 98/171 reads (57%) | called by pindel, varscan2
- FABP5P3 | chr7:152445519 C>T | 3'Flank (SNP) | VAF 160/377 reads (42%) | called by muse, mutect2, varscan2
- LDB3 | c.896+6769G>C | Intron (SNP) | VAF 406/468 reads (87%) | catalogued as COSV99554895; called by muse, varscan2
- MIR129-2 | n.17T>C | RNA (SNP) | VAF 93/107 reads (87%) | called by muse, mutect2, varscan2
- NBPF25P | n.1532G>C | RNA (SNP) | VAF 269/600 reads (45%) | called by muse, mutect2, varscan2
